EXCEPTIONAL_RESPONDERS case ER-B0CR — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c2d664aa-ea0a-465c-8e67-6bb6874b3d73

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 63.3 years (23,120 days); Year of diagnosis: 2015; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 630 days (1.7 years); Days to best overall response: 475 days (1.3 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Cetuximab; Days to treatment start: 49 days; Days to treatment end: 636 days (1.7 years).
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 68 days; Days to treatment end: 265 days.

Follow-up (1 entry)
- Days to follow up: 630 days (1.7 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 630 days (1.7 years); Days progression-free: 475 days (1.3 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0CR-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0CR-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-B0CR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0CR-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 40; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
